Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A726, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A726-01A (Primary Tumor).

[page 1 of 2]
DERMATOPATHOLOGY

Case Number :

ICD 0-3
Melanoma, lentigo maligna
8742/3
Site: Skin, external ear
C44.2
JN8/11/13

Diagnosis:

A: Sentinel lymph node, tail of right parotid #1, removal
-No evidence of melanoma in 1 sentinel lymph node (0/1)
-Immunostains and levels are negative in all five blocks

B: Sentinel lymph node, tail of right parotid #2, removal
-No evidence of melanoma in 2 sentinel lymph nodes (0/2)
-Immunostains and levels are negative in all five blocks

C: Right portion of right ear, excision
Histologic type: Biopsy site changes and residual lentigo
maligna melanoma

Breslow depth: 14 mm(1.4 cm)

Ulceration: PRESENT

Consumption of the epidermis: present

Margins: all margins are widely free

Clark level: IV

Vertical growth phase: present

Mitoses: 26 per square mm

Tumor infiltrating lymphocytes: not identified

Regression: not identified

Lymphovascular space invasion: not identified

Satellite nodule: not identified

Perineural invasion: not identified

Coexisting nevus: not identified

Pigmentation: not identified

Solar elastosis: present, severe

AJCC Staging

pT4b pN0 pMx

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Clinical History:

-year-old male with melanoma

Gross Description:

A: The fibrofatty specimen was received labeled with the patient's name and measured 20 x 10 x 8 mm. The tissue is serially sectioned at very thin intervals and entirely submitted as A1-5,

[page 2 of 2]
B: The fibrofatty specimen was received labeled with the patient's name and two tissues measuring 7 x 5 x 5 mm and 8 x 7 x 5 mm. The tissue is serially sectioned at very thin intervals and entirely submitted as B1-B5 with B1-2 representing the smaller node and B3-5 representing the larger node,

C: The specimen bears a short suture indicating superior and a long suture indicating anterior medial and measures 50 x 27 x 15 mm. Centrally, there is a 2.8 x 1.5 x 1.4 cm nodule with fresh tumor taken by tissue procurement. Viewing the specimen with the short suture at the 12:00 position and the long suture at the 3:00 position, the margin encompassing the 12-3 o' clock position/superior half is inked green, while the inferior half (3-6:00) margin is inked orange.

The 12:00 tip is block 1, the 6:00 tip is block 2, and the middle portion from 12-6 is submitted as blocks 3-11,

Source: NCI Genomic Data Commons file 9ec4249c-8b02-4e46-8820-0657e4a26f57 (TCGA-FR-A726.B9FC0FCB-B439-4354-BFBE-CAC6BCDEC588.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).